Somatic mutation profile of tumor specimen ALCH-B3DK-TTP1-A (aliquot ALCH-B3DK-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B3DK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.8 years (27,323 days).
Specimen ALCH-B3DK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c94f4d2b-b103-4ec9-9c84-ea5b452f8be5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3DK-NB1-A (Blood Derived Normal), aliquot ALCH-B3DK-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14484081-c922-497d-857a-1c21c53fb925

The open-access MAF lists 213 somatic variants for this specimen: 148 protein-altering or splice-affecting, 49 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 49, Intron 10, Nonsense Mutation 10, Splice Site 5, RNA 4, Frame Shift Del 4, Frame Shift Ins 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 157/511 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 55/85 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM012193, CM067471, COSV58820785; called by muse, mutect2, varscan2
- ADAM22 | c.1669A>G p.I557V | Missense Mutation (SNP) | VAF 122/298 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.17); catalogued as rs1330862166; called by muse, mutect2, varscan2
- ADH1A | c.665C>A p.A222E | Missense Mutation (SNP) | VAF 152/808 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs781090973, COSV52924876; called by muse, mutect2, varscan2
- AKAP13 | c.5755A>G p.M1919V (on ENST00000394518 / NM_007200.5; = p.M1923V on NM_006738.6) | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as rs1486121270; called by muse, mutect2, varscan2
- ANKZF1 | c.2077G>T p.A693S | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV55478297; called by muse, mutect2, varscan2
- ARNT | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 64/724 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.086); catalogued as rs772808088; called by muse, mutect2
- ATP6V0A1 | c.2110G>T p.E704* | Nonsense Mutation (SNP) | VAF 90/486 reads (19%) | catalogued as COSV52874946; called by muse, mutect2, varscan2
- BICC1 | c.2342T>A p.V781E | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.878); catalogued as COSV99570119; called by muse, mutect2
- CDH10 | c.1549G>T p.D517Y | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100052499; called by muse, mutect2, varscan2
- CDH10 | c.1069C>G p.P357A | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100051463, COSV52569250; called by muse, mutect2, varscan2
- CHD8 | c.3785C>T p.S1262F (on ENST00000646647 / NM_001170629.2; = p.S983F on NM_020920.4) | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67871220; called by muse, mutect2, varscan2
- COL14A1 | c.3998A>C p.Y1333S | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.991); catalogued as COSV52849474; called by muse, mutect2
- CPXM2 | c.1598C>A p.P533H | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV53857907; called by muse, mutect2, varscan2
- CTNNA3 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101047728; called by muse, mutect2, varscan2
- DCN | c.289A>G p.K97E | Missense Mutation (SNP) | VAF 60/468 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV99272317; called by muse, mutect2, varscan2
- DSP | c.8133G>T p.E2711D | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as rs375348086; called by muse, mutect2, varscan2
- DYNC1I1 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 127/362 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs763887544; called by muse, mutect2, varscan2
- ENTPD7 | c.1377C>G p.F459L | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs1254834466, COSV65111960; called by muse, mutect2, varscan2
- EPHA7 | c.1459del p.E487Nfs*7 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as COSV65178939, COSV65182030; called by pindel, varscan2
- ETV2 | c.534T>A p.C178* | Nonsense Mutation (SNP) | VAF 53/113 reads (47%) | catalogued as COSV55837925; called by muse, mutect2, varscan2
- GAPDHS | c.937T>C p.S313P | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as rs753975422; called by muse, mutect2, varscan2
- GBP5 | c.1465+1G>A p.X489_splice | Splice Site (SNP) | VAF 80/281 reads (28%) | catalogued as rs868042226; called by muse, mutect2, varscan2
- GCGR | c.1313C>A p.S438* | Nonsense Mutation (SNP) | VAF 155/604 reads (26%) | catalogued as COSV68779893; called by muse, mutect2, varscan2
- GPC3 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 260/516 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63663584; called by muse, mutect2, varscan2
- GPR158 | c.772G>C p.G258R | Missense Mutation (SNP) | VAF 50/322 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.455); catalogued as rs1471027947; called by muse, mutect2, varscan2
- HBB | c.425T>A p.L142Q | Missense Mutation (SNP) | VAF 167/920 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as CM962429; called by muse, mutect2, varscan2
- KCNMB4 | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV50691455; called by muse, mutect2, varscan2
- LCOR | c.50G>T p.S17I | Missense Mutation (SNP) | VAF 132/772 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs771529352, COSV63630157; called by muse, mutect2, varscan2
- LIPA | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 48/580 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as rs1428305850; called by muse, mutect2
- LRRC4C | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs767978305, COSV53417350, COSV99536828; called by muse, mutect2, varscan2
- MMEL1 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV56521171; called by muse, mutect2, varscan2
- MOGS | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 43/432 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs745844848, COSV52029041; called by muse, mutect2
- MYO3B | c.3874C>G p.P1292A | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as COSV104397594; called by muse, mutect2
- NGFR | c.140G>C p.C47S | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99412982; called by muse, mutect2, varscan2
- NRXN3 | c.2203C>G p.R735G (on ENST00000335750 / NM_001330195.2; = p.R362G on NM_004796.6) | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1221132660; called by muse, mutect2, varscan2
- OR10D3 | c.607G>C p.V203L | Missense Mutation (SNP) | VAF 233/667 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV59421120; called by muse, mutect2, varscan2
- OR4C15 | c.748C>T p.L250F (on ENST00000314644; = p.L196F on NM_001001920.2) | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.105); catalogued as COSV58953808; called by muse, mutect2
- OR6Q1 | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 176/672 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV100110247; called by muse, mutect2, varscan2
- PCDH11X | c.339del p.I114Ffs*15 | Frame Shift Del (DEL) | VAF 145/405 reads (36%) | catalogued as COSV53508284; called by mutect2, pindel, varscan2
- PDLIM5 | c.737G>T p.R246L | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.194); catalogued as rs141403934, COSV104400861; called by muse, mutect2, varscan2
- PLCB2 | c.1622C>T p.T541M | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as rs777681107, COSV53036084; called by muse, mutect2, varscan2
- PTPRZ1 | c.4382C>A p.T1461N | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.276); catalogued as COSV66433217; called by muse, mutect2, varscan2
- RELN | c.2466-2A>T p.X822_splice | Splice Site (SNP) | VAF 33/298 reads (11%) | catalogued as rs1281375753; called by mutect2, varscan2
- RGS20 | c.709G>A p.E237K (on ENST00000297313 / NM_170587.4; = p.E90K on NM_003702.4) | Missense Mutation (SNP) | VAF 44/416 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as rs770358295; called by muse, mutect2, varscan2
- SIGLEC1 | c.3961G>T p.A1321S | Missense Mutation (SNP) | VAF 147/452 reads (33%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.834); catalogued as COSV99163474; called by muse, mutect2, varscan2
- SIX6 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1446659494, COSV100576576; called by muse, mutect2, varscan2
- SLC24A4 | c.1684G>A p.V562M | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs199781252; called by muse, mutect2
- SLC5A4 | c.20C>G p.P7R | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV56668012; called by muse, mutect2, varscan2
- SPAG17 | c.5093C>A p.A1698E | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV60470235; called by muse, mutect2, varscan2
- SVEP1 | c.9377C>T p.P3126L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376942718; called by muse, mutect2, varscan2
- SYNRG | c.3548G>A p.R1183H | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370465279; called by muse, mutect2, varscan2
- TCF4 | c.1786A>G p.K596E | Missense Mutation (SNP) | VAF 155/958 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV61891378; called by muse, mutect2, varscan2
- TSHZ1 | c.1730C>A p.P577H (on ENST00000580243 / NM_001308210.2; = p.P532H on NM_005786.6) | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV59008418; called by muse, mutect2, varscan2
- VRK2 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 134/461 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100418318; called by muse, mutect2, varscan2
- ZNF479 | c.788A>G p.H263R | Missense Mutation (SNP) | VAF 98/462 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1200615325; called by muse, varscan2
- ZNF649 | c.1423C>G p.P475A | Missense Mutation (SNP) | VAF 60/377 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV100031149; called by muse, mutect2, varscan2
- ZNF746 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.156); catalogued as rs865939023, COSV100502404; called by muse, mutect2, varscan2
- ZNF804B | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 52/472 reads (11%) | catalogued as rs747659636; called by muse, mutect2, varscan2
- ACSL6 | c.2014C>T p.P672S (on ENST00000379240; = p.P697S on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/365 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTG2 | c.1048C>A p.L350I | Missense Mutation (SNP) | VAF 126/453 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB3 | c.2656G>T p.G886C | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADGRG4 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- ADGRL1 | c.4220A>T p.E1407V (on ENST00000340736 / NM_001008701.3; = p.E1402V on NM_014921.5) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- AGRN | c.5587G>A p.D1863N | Missense Mutation (SNP) | VAF 59/369 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ANKRD36 | c.3781C>G p.P1261A | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- AOX1 | c.2367G>C p.L789F | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APOM | c.236dup p.M80Dfs*27 | Frame Shift Ins (INS) | VAF 39/360 reads (11%) | called by mutect2, pindel, varscan2
- ATP12A | c.2716G>T p.E906* | Nonsense Mutation (SNP) | VAF 51/128 reads (40%) | called by muse, mutect2, varscan2
- BICRAL | c.89del p.S30Lfs*6 | Frame Shift Del (DEL) | VAF 17/133 reads (13%) | called by mutect2, pindel, varscan2
- C12orf50 | c.545C>A p.S182* | Nonsense Mutation (SNP) | VAF 26/460 reads (6%) | called by muse, mutect2
- CCDC180 | c.4513G>T p.V1505F | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC58 | c.227C>G p.A76G | Missense Mutation (SNP) | VAF 56/367 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CFAP54 | c.3387A>C p.R1129S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- CFAP54 | c.3388G>T p.V1130L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.871); called by muse, mutect2
- CFAP69 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CGNL1 | c.3410A>G p.E1137G | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- COL14A1 | c.4000G>T p.D1334Y | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL6A3 | c.2919C>A p.F973L | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPXCR1 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- CSMD3 | c.1727G>T p.W576L (on ENST00000297405 / NM_001363185.1; = p.W472L on NM_052900.3) | Missense Mutation (SNP) | VAF 66/392 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- CTNND2 | c.3446C>A p.P1149H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- DCAF8L2 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 93/204 reads (46%) | called by muse, mutect2, varscan2
- DNAH3 | c.2933A>T p.N978I | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNASE2B | c.219G>T p.W73C | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DPY19L2 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- EHMT1 | c.412A>G p.R138G | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- EMC10 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EXOC3L2 | c.2121-1G>T p.X707_splice | Splice Site (SNP) | VAF 181/377 reads (48%) | called by muse, mutect2, varscan2
- EXOC6B | c.175A>T p.N59Y | Missense Mutation (SNP) | VAF 54/341 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- FGFBP1 | c.171dup p.G58Rfs*17 | Frame Shift Ins (INS) | VAF 56/320 reads (18%) | called by mutect2, pindel, varscan2
- FLG2 | c.4351G>T p.G1451* | Nonsense Mutation (SNP) | VAF 118/1487 reads (8%) | called by muse, mutect2
- FLG2 | c.1942G>T p.G648C | Missense Mutation (SNP) | VAF 100/1194 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- FOXJ3 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GAS2L1 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- GID8 | c.64T>A p.L22M | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- HKDC1 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSD17B2 | c.1155G>T p.K385N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.087); called by muse, varscan2
- IARS1 | c.2668A>T p.I890F | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- IGHV2-26 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 79/523 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IHH | c.1199G>T p.S400I | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- IL1RL2 | c.657A>T p.R219S | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INSM1 | c.5C>G p.P2R | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KCNT2 | c.1817G>A p.C606Y | Missense Mutation (SNP) | VAF 131/557 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KCTD20 | c.256G>C p.G86R | Missense Mutation (SNP) | VAF 93/302 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KDM4E | c.821A>T p.Y274F | Missense Mutation (SNP) | VAF 168/433 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIF19 | c.2915G>T p.G972V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- MADD | c.4024G>T p.D1342Y | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MALRD1 | c.4814A>T p.K1605M | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MMUT | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MTHFD1L | c.2581G>A p.V861I | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MUC16 | c.35098C>T p.P11700S | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MYO7A | c.2176A>C p.I726L | Missense Mutation (SNP) | VAF 23/296 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); called by muse, mutect2
- NPFFR2 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 69/366 reads (19%) | called by muse, mutect2, varscan2
- NPIPB2 | c.962A>T p.K321M (on ENST00000399147; = p.K181M on NM_001355514.1) | Missense Mutation (SNP) | VAF 432/1189 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- NR1H4 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR2E1 | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 65/433 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NUDT21 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR11A1 | c.698C>G p.A233G | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- OR4K2 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 59/537 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- OR5AS1 | c.782A>T p.Q261L | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PANX3 | c.1070C>A p.T357N | Missense Mutation (SNP) | VAF 36/321 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEC | c.1829G>T p.R610M (on ENST00000322810 / NM_201380.4; = p.R500M on NM_000445.5) | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PPL | c.1363A>T p.T455S | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- PSG4 | c.1243+1G>T p.X415_splice | Splice Site (SNP) | VAF 97/218 reads (44%) | called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.395G>T p.R132L (on ENST00000407184; = p.G112* on NM_001204513.3) | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- RUNDC3B | c.881A>G p.E294G | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- SH2B2 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC39A12 | c.1558G>T p.A520S (on ENST00000377369 / NM_001145195.2; = p.A483S on NM_152725.3) | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SMPD4 | c.2389A>T p.R797W (on ENST00000409031 / NM_017951.4; = p.R768W on NM_017751.4) | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- TAF3 | c.873del p.P292Qfs*44 | Frame Shift Del (DEL) | VAF 101/435 reads (23%) | called by mutect2, pindel, varscan2
- TDRD15 | c.1699G>T p.D567Y | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM184A | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 97/251 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- TNR | c.199C>G p.H67D | Missense Mutation (SNP) | VAF 123/707 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPRN | c.1490G>A p.G497D | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); called by muse, varscan2
- TRIM64B | c.849C>A p.N283K | Missense Mutation (SNP) | VAF 41/904 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2
- UGT2B15 | c.1093+1G>C p.X365_splice | Splice Site (SNP) | VAF 58/355 reads (16%) | called by muse, mutect2, varscan2
- VEGFB | c.593C>G p.A198G | Missense Mutation (SNP) | VAF 38/356 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.588); called by muse, mutect2
- VPS13C | c.10277C>T p.P3426L (on ENST00000644861 / NM_020821.3; = p.P3383L on NM_017684.5) | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VWA3B | c.262T>A p.Y88N | Missense Mutation (SNP) | VAF 152/488 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WDFY4 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 62/430 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ZFYVE26 | c.6110G>T p.R2037M | Missense Mutation (SNP) | VAF 128/762 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF131 | c.40C>G p.P14A | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ZNF420 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF438 | c.2103G>C p.W701C | Missense Mutation (SNP) | VAF 66/516 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF479 | c.891C>A p.Y297* | Nonsense Mutation (SNP) | VAF 60/552 reads (11%) | called by muse, varscan2
- ZNF862 | c.2435A>T p.Q812L | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ZP4 | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ABCC11 | c.1890G>A p.R630= | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as rs954148790; called by muse, mutect2, varscan2
- ACHE | c.330T>A p.G110= | Silent (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- ADAM21 | c.1272C>T p.S424= | Silent (SNP) | VAF 70/758 reads (9%) | catalogued as rs767652252; called by muse, mutect2
- AFDN | c.2334C>T p.V778= | Silent (SNP) | VAF 105/475 reads (22%) | called by muse, mutect2, varscan2
- AGT | c.1366C>T p.L456= | Silent (SNP) | VAF 68/631 reads (11%) | called by muse, mutect2, varscan2
- AHNAK | c.6837G>C p.V2279= | Silent (SNP) | VAF 123/841 reads (15%) | called by muse, mutect2, varscan2
- ANGPT1 | c.537A>G p.Q179= | Silent (SNP) | VAF 41/183 reads (22%) | catalogued as rs766925675; called by muse, mutect2, varscan2
- ASS1 | c.735G>A p.Q245= | Silent (SNP) | VAF 135/634 reads (21%) | catalogued as rs1193882026; called by muse, mutect2, varscan2
- BICD2 | c.2091C>G p.L697= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs754613422; called by muse, mutect2
- CACNA1F | c.1638C>T p.I546= | Silent (SNP) | VAF 13/197 reads (7%) | catalogued as rs376114458; called by muse, mutect2
- CCDC50 | c.972C>T p.D324= | Silent (SNP) | VAF 33/240 reads (14%) | catalogued as rs752997734; called by muse, mutect2, varscan2
- CDHR2 | c.2508G>T p.V836= | Silent (SNP) | VAF 48/319 reads (15%) | called by muse, mutect2, varscan2
- CHRNA7 | c.1020G>T p.A340= | Silent (SNP) | VAF 32/268 reads (12%) | catalogued as rs768502457, COSV100181095; called by mutect2, varscan2
- CLCA2 | c.1728T>G p.T576= | Silent (SNP) | VAF 13/288 reads (5%) | called by muse, mutect2
- CPA6 | c.1227C>T p.L409= | Silent (SNP) | VAF 33/396 reads (8%) | called by muse, mutect2
- DCAF4L2 | c.879T>A p.T293= | Silent (SNP) | VAF 28/314 reads (9%) | called by muse, mutect2
- DENND1A | c.279G>C p.A93= | Silent (SNP) | VAF 40/190 reads (21%) | catalogued as COSV65322878; called by muse, mutect2, varscan2
- ERICH3 | c.4158C>A p.T1386= | Silent (SNP) | VAF 58/346 reads (17%) | called by muse, mutect2, varscan2
- FAM186A | c.3264T>C p.T1088= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as rs1166420693; called by muse, mutect2, varscan2
- FBXO3 | c.531C>T p.V177= | Silent (SNP) | VAF 38/498 reads (8%) | catalogued as rs762175150, COSV55767723; called by muse, mutect2
- FLG | c.9258A>G p.R3086= | Silent (SNP) | VAF 62/1491 reads (4%) | called by muse, mutect2
- HK1 | c.2574G>T p.V858= | Silent (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- HMCN2 | c.15087C>G p.R5029= | Silent (SNP) | VAF 20/90 reads (22%) | called by muse, mutect2, varscan2
- IGSF11 | c.1032T>G p.S344= (on ENST00000393775 / NM_001015887.3; = p.S343= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 88/584 reads (15%) | called by muse, mutect2, varscan2
- IQSEC3 | c.3180G>A p.A1060= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs755811178, COSV58286927; called by muse, mutect2, varscan2
- LTB4R2 | c.471C>G p.P157= (on ENST00000528054; = p.P126= on NM_019839.5) | Silent (SNP) | VAF 32/266 reads (12%) | called by muse, mutect2, varscan2
- MDGA2 | c.123A>G p.R41= | Silent (SNP) | VAF 10/354 reads (3%) | catalogued as COSV101229917, COSV67811025; called by muse, mutect2
- MMP10 | c.762T>C p.D254= | Silent (SNP) | VAF 82/222 reads (37%) | catalogued as rs369185884; called by muse, mutect2, varscan2
- MRPS5 | c.12G>T p.A4= | Silent (SNP) | VAF 80/272 reads (29%) | catalogued as rs969762305; called by muse, mutect2, varscan2
- OAS2 | c.1554A>C p.G518= | Silent (SNP) | VAF 21/199 reads (11%) | called by muse, mutect2
- OR6K2 | c.711A>T p.T237= | Silent (SNP) | VAF 54/502 reads (11%) | catalogued as rs766453910; called by muse, mutect2, varscan2
- PRRT4 | c.612G>T p.R204= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- SGK2 | c.825G>T p.V275= | Silent (SNP) | VAF 139/477 reads (29%) | called by muse, mutect2, varscan2
- SLC30A10 | c.129C>T p.N43= | Silent (SNP) | VAF 119/647 reads (18%) | called by muse, mutect2, varscan2
- SLITRK2 | c.912G>C p.P304= | Silent (SNP) | VAF 88/190 reads (46%) | called by muse, mutect2, varscan2
- SORCS3 | c.2454A>T p.G818= | Silent (SNP) | VAF 51/211 reads (24%) | called by muse, mutect2, varscan2
- SPOCK3 | c.30G>A p.V10= | Silent (SNP) | VAF 38/296 reads (13%) | called by mutect2, varscan2
- TARBP1 | c.519C>T p.G173= | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as rs1187483704; called by muse, mutect2
- TLL1 | c.2412C>A p.I804= | Silent (SNP) | VAF 158/915 reads (17%) | catalogued as COSV99286466; called by muse, mutect2, varscan2
- TMEM109 | c.69G>T p.V23= | Silent (SNP) | VAF 89/625 reads (14%) | called by muse, mutect2, varscan2
- TP53BP2 | c.1056A>T p.A352= (on ENST00000343537 / NM_001031685.3; = p.A223= on NM_005426.2) | Silent (SNP) | VAF 131/660 reads (20%) | called by muse, mutect2, varscan2
- TRIM65 | c.699G>A p.R233= | Silent (SNP) | VAF 35/206 reads (17%) | called by muse, mutect2, varscan2
- TRPA1 | c.1629C>T p.R543= | Silent (SNP) | VAF 90/959 reads (9%) | called by muse, mutect2
- TRPM3 | c.801A>C p.G267= (on ENST00000357533 / NM_001366142.2; = p.G112= on NM_020952.6) | Silent (SNP) | VAF 38/195 reads (19%) | called by muse, mutect2, varscan2
- TSC22D1 | c.1308A>T p.V436= | Silent (SNP) | VAF 64/171 reads (37%) | called by muse, mutect2, varscan2
- VWA8 | c.616C>T p.L206= | Silent (SNP) | VAF 101/263 reads (38%) | called by muse, mutect2, varscan2
- ZNF521 | c.1188C>T p.P396= | Silent (SNP) | VAF 43/281 reads (15%) | called by muse, mutect2, varscan2
- ZNF676 | c.1095A>C p.G365= (on ENST00000650058; = p.G333= on NM_001001411.3) | Silent (SNP) | VAF 75/884 reads (8%) | called by muse, mutect2
- ZNF862 | c.411G>T p.R137= | Silent (SNP) | VAF 168/415 reads (40%) | catalogued as COSV56225681; called by muse, mutect2, varscan2
- CEP170 | c.1843+72C>G | Intron (SNP) | VAF 40/134 reads (30%) | called by muse, varscan2
- FOLH1B | n.1004G>T | RNA (SNP) | VAF 136/387 reads (35%) | called by muse, mutect2, varscan2
- GABRB1 | c.240+200C>A | Intron (SNP) | VAF 30/225 reads (13%) | called by muse, mutect2, varscan2
- GPA33 | c.43+7950A>G | Intron (SNP) | VAF 99/530 reads (19%) | called by muse, varscan2
- H3-3B | chr17:75784641 C>A | 5'Flank (SNP) | VAF 167/603 reads (28%) | called by muse, mutect2, varscan2
- HSP90B3P | n.964A>G | RNA (SNP) | VAF 128/303 reads (42%) | called by muse, mutect2, varscan2
- KRT8P11 | n.516A>T | RNA (SNP) | VAF 88/369 reads (24%) | called by muse, mutect2, varscan2
- LILRB1 | c.1800+117del | Intron (DEL) | VAF 286/582 reads (49%) | called by mutect2, varscan2
- LRATD1 | c.*685G>A | 3'UTR (SNP) | VAF 159/441 reads (36%) | called by muse, mutect2, varscan2
- MIR518A1 | n.28C>A | RNA (SNP) | VAF 142/298 reads (48%) | called by muse, mutect2, varscan2
- PDGFB | c.63+2998_63+2999insTAGA | Intron (INS) | VAF 41/183 reads (22%) | called by mutect2, pindel
- RAB26 | c.307-395T>A | Intron (SNP) | VAF 62/179 reads (35%) | called by muse, mutect2, varscan2
- RAP1GAP | c.1429-808C>A | Intron (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- SHOC2 | c.841+3224C>T | Intron (SNP) | VAF 65/255 reads (25%) | called by muse, mutect2, varscan2
- TRAPPC3L | c.43-461T>A | Intron (SNP) | VAF 61/302 reads (20%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4111C>A | Intron (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
